Somatic mutation profile of tumor specimen ALCH-B3AY-TTP1-A (aliquot ALCH-B3AY-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3AY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.4 years (20,582 days).
Specimen ALCH-B3AY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be49e0d0-4086-44a1-941c-c14ad880578e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3AY-NB1-A (Blood Derived Normal), aliquot ALCH-B3AY-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7a57074-a134-4de8-a135-04f8095e013d

The open-access MAF lists 233 somatic variants for this specimen: 153 protein-altering or splice-affecting, 54 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 54, Nonsense Mutation 13, Intron 11, Splice Site 7, RNA 6, 5'UTR 4, Frame Shift Del 3, 3'Flank 2, 3'UTR 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 48/146 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262468, COSV50595028; called by muse, mutect2, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 227/660 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 115/294 reads (39%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 172/1072 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.664); catalogued as rs748268010; called by muse, mutect2, varscan2
- ADGRL3 | c.3002G>T p.R1001L (on ENST00000506720 / NM_001322402.2; = p.R933L on NM_015236.6) | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as rs370040630; called by muse, mutect2, varscan2
- AFAP1L1 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.988); catalogued as COSV99695926; called by muse, mutect2, varscan2
- AKR7A2 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 194/921 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs573103736; called by muse, mutect2, varscan2
- APBA2 | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 207/682 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV101258199; called by muse, mutect2, varscan2
- ATP2B2 | c.1111G>C p.E371Q (on ENST00000352432; = p.E337Q on NM_001683.5) | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59505910; called by muse, mutect2
- ATP5PF | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as COSV53167303; called by muse, varscan2
- CCDC125 | c.752A>G p.Q251R | Missense Mutation (SNP) | VAF 64/384 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs748530090; called by muse, mutect2, varscan2
- CCNP | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs1342220687; called by muse, mutect2
- CEP89 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs1282304472; called by muse, mutect2, varscan2
- CFAP47 | c.5039A>C p.K1680T | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV100545267; called by muse, mutect2, varscan2
- CNTN4 | c.689A>T p.Q230L | Missense Mutation (SNP) | VAF 31/945 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV61870557; called by muse, mutect2
- CNTN6 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100611804; called by muse, mutect2, varscan2
- COL22A1 | c.3517C>T p.R1173C | Missense Mutation (SNP) | VAF 346/1352 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs765086524, COSV57325698; called by muse, mutect2, varscan2
- CWH43 | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141315226, COSV56937388, COSV99893295; called by muse, mutect2, varscan2
- DNAH6 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104378726, COSV99405613; called by muse, mutect2, varscan2
- DRC1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 130/579 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs769270156, COSV55496136; called by muse, mutect2, varscan2
- DTX1 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.872); catalogued as rs1433417872; called by muse, mutect2, varscan2
- ELMO1 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 101/462 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100165624; called by muse, mutect2, varscan2
- GMPPB | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as rs755165049, COSV57537510; ClinVar: uncertain significance; called by muse, mutect2
- GRID2 | c.1172G>C p.G391A | Missense Mutation (SNP) | VAF 69/357 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.315); catalogued as COSV56284652; called by muse, mutect2, varscan2
- GRID2 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1230071122; called by muse, mutect2, varscan2
- HCN1 | c.1946C>A p.S649Y | Missense Mutation (SNP) | VAF 200/2292 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as COSV100302693, COSV57525389; called by muse, mutect2
- HDAC9 | c.3195G>T p.E1065D (on ENST00000441542 / NM_178425.3; = p.E1062D on NM_178423.3) | Missense Mutation (SNP) | VAF 54/630 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV101286817; called by muse, mutect2
- KIR3DL2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 140/940 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.773); catalogued as rs1333214201, COSV54391080; called by muse, mutect2, varscan2
- MACF1 | c.18259-1G>T p.X6087_splice (on ENST00000372915; = p.X4132_splice on NM_012090.5) | Splice Site (SNP) | VAF 93/361 reads (26%) | catalogued as COSV57117431; called by muse, mutect2, varscan2
- MMAB | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 58/510 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749758687, CD023284, CM023192, COSV99904461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC5AC | c.13427G>T p.G4476V | Missense Mutation (SNP) | VAF 118/796 reads (15%) | SIFT tolerated (0.56); catalogued as rs1554928975, COSV64369328; called by muse, varscan2
- NLRP5 | c.3297C>A p.L1099= | Splice Region (SNP) | VAF 33/77 reads (43%) | catalogued as COSV66761796; called by muse, mutect2, varscan2
- NPAS3 | c.2306G>T p.G769V (on ENST00000356141 / NM_001164749.2; = p.G737V on NM_022123.3) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as rs759209493; called by muse, mutect2, varscan2
- NUBPL | c.927A>T p.E309D | Missense Mutation (SNP) | VAF 135/1656 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs1210887298; called by muse, mutect2
- OBSCN | c.23864G>T p.R7955L | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV62330650; called by muse, mutect2, varscan2
- OR10Z1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 104/411 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs145085081, COSV100778934; called by muse, mutect2, varscan2
- OR2J3 | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV65848875; called by muse, mutect2
- OR4X2 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.744); catalogued as rs765250014, COSV56582260; called by muse, mutect2
- PLLP | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99536445; called by muse, varscan2
- PPARGC1A | c.2029C>A p.R677S | Missense Mutation (SNP) | VAF 61/415 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53532775; called by muse, mutect2, varscan2
- PTPRQ | c.2972G>A p.S991N (on ENST00000616559; = p.S949N on NM_001145026.2) | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.132); catalogued as COSV57034791; called by muse, mutect2
- REG1A | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 213/1141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52069986; called by muse, mutect2, varscan2
- RPS6KA4 | c.1845G>T p.Q615H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.516); catalogued as COSV99589838; called by muse, mutect2, varscan2
- RTKN2 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 39/390 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100189691; called by muse, mutect2
- SEMA3E | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 185/1579 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV104410695; called by muse, mutect2, varscan2
- SUGP2 | c.2695G>T p.D899Y | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100432497; called by muse, mutect2, varscan2
- TP53BP2 | c.2138C>G p.S713C (on ENST00000343537 / NM_001031685.3; = p.S584C on NM_005426.2) | Missense Mutation (SNP) | VAF 138/782 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100636497, COSV59066985; called by muse, mutect2, varscan2
- TRIM51GP | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 300/1201 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.391); catalogued as rs778246517; called by mutect2, varscan2
- TYK2 | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99314433; called by muse, mutect2
- USH2A | c.9677G>T p.R3226L | Missense Mutation (SNP) | VAF 174/873 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV100243242; called by muse, mutect2, varscan2
- WNT16 | c.31C>A p.R11S | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs867332829; called by muse, varscan2
- XIRP2 | c.3697C>A p.P1233T (on ENST00000628543; = p.P1408T on NM_152381.6) | Missense Mutation (SNP) | VAF 84/367 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs757742625; called by muse, mutect2, varscan2
- ZNF502 | c.1584C>G p.F528L | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV56075178; called by muse, mutect2
- ABCC12 | c.3681G>A p.W1227* | Nonsense Mutation (SNP) | VAF 36/319 reads (11%) | called by muse, mutect2, varscan2
- ADGB | c.1628T>A p.L543* | Nonsense Mutation (SNP) | VAF 22/642 reads (3%) | called by muse, mutect2
- ADGRL2 | c.2307T>A p.D769E (on ENST00000370717 / NM_001366005.1; = p.D756E on NM_012302.4) | Missense Mutation (SNP) | VAF 116/643 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADGRL3 | c.4486C>A p.L1496M (on ENST00000506720 / NM_001322402.2; = p.L1385M on NM_015236.6) | Missense Mutation (SNP) | VAF 87/605 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGEF3 | c.3897G>T p.L1299F | Missense Mutation (SNP) | VAF 123/522 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASIC4 | c.350T>A p.L117H | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ATP8B4 | c.2672G>T p.G891V | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- AUTS2 | c.1735-2A>T p.X579_splice | Splice Site (SNP) | VAF 32/172 reads (19%) | called by muse, mutect2, varscan2
- BCHE | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 63/576 reads (11%) | called by muse, mutect2, varscan2
- BCL9L | c.4450C>T p.Q1484* | Nonsense Mutation (SNP) | VAF 14/149 reads (9%) | called by muse, mutect2, varscan2
- BTD | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- CALD1 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 45/416 reads (11%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1181T>A p.L394Q | Missense Mutation (SNP) | VAF 109/1013 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- COL18A1 | c.3769C>T p.P1257S (on ENST00000359759 / NM_130444.3; = p.P1022S on NM_030582.4) | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A4 | c.2524C>G p.P842A | Missense Mutation (SNP) | VAF 26/938 reads (3%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.787); called by muse, mutect2
- CPXCR1 | c.394T>A p.F132I | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CREB5 | c.1354G>T p.G452* (on ENST00000357727 / NM_182898.4; = p.G445* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 138/533 reads (26%) | called by muse, mutect2, varscan2
- CSMD1 | c.10186G>T p.V3396L (on ENST00000520002; = p.V3395L on NM_033225.6) | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEFB127 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 38/383 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- ENTPD7 | c.1547G>C p.G516A | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERVV-2 | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by mutect2, varscan2
- F5 | c.2416G>T p.A806S | Missense Mutation (SNP) | VAF 136/735 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FAM50A | c.830-2A>T p.X277_splice | Splice Site (SNP) | VAF 77/238 reads (32%) | called by muse, mutect2, varscan2
- FGF12 | c.176dup p.R60Efs*35 | Frame Shift Ins (INS) | VAF 63/246 reads (26%) | called by mutect2, pindel, varscan2
- FHOD3 | c.357C>A p.S119R | Missense Mutation (SNP) | VAF 80/464 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- FOXP1 | c.505A>T p.K169* | Nonsense Mutation (SNP) | VAF 203/1323 reads (15%) | called by muse, mutect2, varscan2
- FPGS | c.540C>G p.F180L | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- GALNT13 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 112/523 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- GART | c.2810C>T p.T937I | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GART | c.2809A>T p.T937S | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLGA3 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPC6 | c.863G>A p.W288* | Nonsense Mutation (SNP) | VAF 171/898 reads (19%) | called by muse, mutect2, varscan2
- GPR27 | c.1064G>T p.C355F | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRIP2 | c.1117A>G p.I373V (on ENST00000619221; = p.I276V on NM_001080423.4) | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- H1-2 | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 115/515 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- HKDC1 | c.2507G>A p.G836D | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-C | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- IGHD | c.190T>C p.Y64H | Missense Mutation (SNP) | VAF 59/433 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- IGKV3D-20 | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 224/1173 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ING2 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ING3 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 269/818 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ITGA3 | c.3118C>T p.Q1040* | Nonsense Mutation (SNP) | VAF 28/400 reads (7%) | called by muse, mutect2
- LAMB2 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LRRC8C | c.1257G>T p.Q419H | Missense Mutation (SNP) | VAF 87/521 reads (17%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MATN2 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- MATN2 | c.1943-1G>A p.X648_splice | Splice Site (SNP) | VAF 24/116 reads (21%) | called by muse, varscan2
- MBNL1 | c.277A>C p.M93L | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MCM3AP | c.4546del p.D1516Mfs*3 | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | called by mutect2, pindel*
- MIDEAS | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2
- MROH1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 133/484 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MROH2B | c.2275A>T p.I759F | Missense Mutation (SNP) | VAF 39/893 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- MTUS2 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC19 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 69/356 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- MYO5A | c.2209-1G>T p.X737_splice | Splice Site (SNP) | VAF 156/785 reads (20%) | called by muse, mutect2, varscan2
- MYO6 | c.1643A>G p.H548R | Missense Mutation (SNP) | VAF 121/1209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- NCAN | c.2696C>A p.P899Q | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NEXN | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 133/835 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOTCH4 | c.5071del p.Q1691Kfs*15 | Frame Shift Del (DEL) | VAF 33/237 reads (14%) | called by mutect2, pindel, varscan2
- NUTM2G | c.1801G>A p.G601R | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- OCLN | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 113/656 reads (17%) | called by muse, mutect2, varscan2
- OR14K1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 97/765 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR2D3 | c.778C>A p.H260N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR3A1 | c.255G>T p.L85F | Missense Mutation (SNP) | VAF 107/666 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR5J2 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 82/347 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- OR6B2 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 84/550 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, varscan2
- OTOF | c.3335T>A p.V1112E (on ENST00000272371 / NM_194248.3; = p.V365E on NM_004802.4) | Missense Mutation (SNP) | VAF 89/397 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PARVB | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHB16 | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 213/847 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB16 | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 215/850 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB4 | c.39G>T p.R13S | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.295); called by muse, varscan2
- PDS5A | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 33/301 reads (11%) | called by muse, mutect2, varscan2
- PLA2G4A | c.1280A>T p.K427M | Missense Mutation (SNP) | VAF 100/640 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PLXNA4 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 187/572 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- POLR2A | c.4353G>T p.M1451I | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- POLR2H | c.157+1_157+10del p.X53_splice | Splice Site (DEL) | VAF 57/274 reads (21%) | called by mutect2, pindel, varscan2
- PRDM2 | c.1652A>T p.D551V | Missense Mutation (SNP) | VAF 126/710 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRSS35 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 88/398 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SATL1 | c.470C>A p.A157E (on ENST00000395409; = p.A344E on NM_001012980.2) | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SFTPB | c.890_891del p.S297* | Frame Shift Del (DEL) | VAF 131/839 reads (16%) | called by pindel, varscan2
- SPAM1 | c.705T>G p.N235K | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2
- SPATA31D3 | c.2440T>A p.S814T | Missense Mutation (SNP) | VAF 95/948 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SRRM2 | c.3904G>T p.A1302S | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ST8SIA6 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- STXBP5L | c.2232C>A p.C744* | Nonsense Mutation (SNP) | VAF 59/394 reads (15%) | called by muse, mutect2, varscan2
- TBC1D32 | c.1721C>G p.S574C | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TBC1D8B | c.1491G>T p.W497C | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TEX45 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TIAM1 | c.268T>A p.W90R | Missense Mutation (SNP) | VAF 84/410 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM121 | c.74T>C p.M25T | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRAV27 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 116/663 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM51GP | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 194/905 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TTN | c.67249C>A p.P22417T (on ENST00000591111; = p.P14993T on NM_003319.4) | Missense Mutation (SNP) | VAF 35/462 reads (8%) | PolyPhen benign (0.132); called by muse, mutect2
- USH2A | c.6241G>T p.A2081S | Missense Mutation (SNP) | VAF 282/846 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- USP45 | c.2427C>G p.F809L | Missense Mutation (SNP) | VAF 15/543 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR33 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 26/413 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF440 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2
- ZNF479 | c.812G>C p.C271S | Missense Mutation (SNP) | VAF 70/635 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNRF3 | c.2374G>T p.G792* (on ENST00000544604 / NM_001206998.2; = p.G692* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 46/125 reads (37%) | called by muse, mutect2, varscan2
- ZP4 | c.1537T>C p.S513P | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ZSCAN10 | c.865G>A p.E289K (on ENST00000252463; = p.E344K on NM_032805.3) | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACAN | c.6876C>A p.T2292= | Silent (SNP) | VAF 60/201 reads (30%) | called by muse, mutect2, varscan2
- ARSB | c.702C>G p.L234= | Silent (SNP) | VAF 73/643 reads (11%) | called by muse, mutect2, varscan2
- ATP5PF | c.213G>T p.L71= | Silent (SNP) | VAF 106/589 reads (18%) | called by muse, mutect2, varscan2
- ATP8B4 | c.513G>C p.T171= | Silent (SNP) | VAF 48/209 reads (23%) | catalogued as COSV52710214, COSV52716049; called by muse, mutect2, varscan2
- BSN | c.2100C>T p.V700= | Silent (SNP) | VAF 20/157 reads (13%) | catalogued as rs773227744; called by muse, mutect2, varscan2
- CAMK2B | c.981C>A p.S327= | Silent (SNP) | VAF 45/426 reads (11%) | called by muse, mutect2, varscan2
- CDK13 | c.3231A>T p.A1077= | Silent (SNP) | VAF 49/198 reads (25%) | catalogued as rs752737137; called by muse, mutect2, varscan2
- CLCN1 | c.2874G>A p.E958= | Silent (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- CLCN3 | c.1380T>C p.F460= | Silent (SNP) | VAF 59/530 reads (11%) | called by muse, mutect2, varscan2
- CNKSR1 | c.612G>A p.L204= | Silent (SNP) | VAF 56/516 reads (11%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.987C>T p.C329= | Silent (SNP) | VAF 32/244 reads (13%) | called by muse, mutect2, varscan2
- COL11A1 | c.4443T>A p.S1481= | Silent (SNP) | VAF 80/875 reads (9%) | called by muse, mutect2
- CST1 | c.201G>T p.P67= | Silent (SNP) | VAF 57/278 reads (21%) | catalogued as rs766339492; called by muse, mutect2, varscan2
- CTTN | c.948G>T p.R316= | Silent (SNP) | VAF 31/199 reads (16%) | catalogued as rs756532928, COSV57232306; called by muse, mutect2, varscan2
- CTTNBP2 | c.2292G>A p.L764= | Silent (SNP) | VAF 39/758 reads (5%) | catalogued as COSV50497268; called by muse, mutect2
- CWH43 | c.1080C>T p.I360= | Silent (SNP) | VAF 43/390 reads (11%) | catalogued as rs769722314; called by muse, mutect2, varscan2
- DNAH9 | c.9133C>T p.L3045= | Silent (SNP) | VAF 133/695 reads (19%) | catalogued as rs1422557385; called by muse, mutect2, varscan2
- DOCK2 | c.2949C>T p.N983= | Silent (SNP) | VAF 65/305 reads (21%) | catalogued as rs746458293; called by muse, mutect2, varscan2
- DOP1B | c.1243C>T p.L415= | Silent (SNP) | VAF 73/286 reads (26%) | called by muse, varscan2
- EGFR | c.876G>A p.V292= | Silent (SNP) | VAF 74/628 reads (12%) | called by muse, mutect2, varscan2
- EML5 | c.1857A>T p.S619= | Silent (SNP) | VAF 63/496 reads (13%) | called by muse, mutect2, varscan2
- GABRA6 | c.453C>T p.T151= | Silent (SNP) | VAF 212/1063 reads (20%) | called by muse, mutect2, varscan2
- GADL1 | c.498T>C p.F166= | Silent (SNP) | VAF 44/430 reads (10%) | called by muse, mutect2
- GAS2L3 | c.594A>G p.E198= | Silent (SNP) | VAF 35/339 reads (10%) | called by muse, mutect2, varscan2
- HEATR6 | c.645G>C p.L215= | Silent (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- HSPG2 | c.7884C>T p.V2628= | Silent (SNP) | VAF 63/281 reads (22%) | catalogued as rs774285421; called by muse, mutect2, varscan2
- INSRR | c.1062C>T p.L354= | Silent (SNP) | VAF 42/604 reads (7%) | catalogued as rs999102344; called by muse, mutect2
- KERA | c.822C>G p.L274= | Silent (SNP) | VAF 30/226 reads (13%) | called by muse, mutect2, varscan2
- MAP3K7 | c.402T>C p.C134= | Silent (SNP) | VAF 40/992 reads (4%) | catalogued as COSV65233601; called by muse, mutect2
- MCM7 | c.222G>C p.A74= | Silent (SNP) | VAF 99/494 reads (20%) | catalogued as COSV57995524; called by muse, mutect2, varscan2
- MUC3A | c.8838C>T p.T2946= | Silent (SNP) | VAF 39/122 reads (32%) | called by muse, varscan2
- NLGN3 | c.78G>T p.L26= | Silent (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- NPAS1 | c.1173G>A p.K391= | Silent (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- OR7C1 | c.903G>T p.L301= | Silent (SNP) | VAF 81/237 reads (34%) | catalogued as rs772459616; called by muse, mutect2, varscan2
- OR8B2 | c.585C>T p.N195= | Silent (SNP) | VAF 120/540 reads (22%) | catalogued as rs761030464, COSV66664104; called by muse, mutect2, varscan2
- OTOF | c.5901C>G p.L1967= (on ENST00000272371 / NM_194248.3; = p.L1200= on NM_004802.4) | Silent (SNP) | VAF 29/273 reads (11%) | called by muse, mutect2, varscan2
- PCDH18 | c.1287T>A p.S429= | Silent (SNP) | VAF 32/161 reads (20%) | called by muse, mutect2, varscan2
- PCDHB15 | c.1737G>T p.A579= | Silent (SNP) | VAF 37/511 reads (7%) | catalogued as COSV50913702; called by muse, mutect2, varscan2
- PDE4D | c.381G>T p.A127= | Silent (SNP) | VAF 163/624 reads (26%) | called by muse, mutect2, varscan2
- PERM1 | c.1773C>T p.T591= | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2
- PKHD1 | c.5254C>T p.L1752= | Silent (SNP) | VAF 43/1348 reads (3%) | called by muse, mutect2
- PLCXD3 | c.678C>A p.I226= | Silent (SNP) | VAF 68/890 reads (8%) | catalogued as COSV60606176; called by muse, mutect2
- PPM1H | c.1539G>T p.L513= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as rs377235752; called by muse, mutect2, varscan2
- RAI1 | c.4758G>A p.L1586= | Silent (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- SLC3A1 | c.426G>C p.L142= | Silent (SNP) | VAF 61/701 reads (9%) | called by muse, mutect2
- SLC47A2 | c.1743T>C p.A581= | Silent (SNP) | VAF 162/516 reads (31%) | called by muse, mutect2, varscan2
- SLC4A7 | c.2865G>A p.L955= | Silent (SNP) | VAF 44/312 reads (14%) | called by muse, mutect2, varscan2
- SPCS1 | c.426C>T p.L142= (on ENST00000233025; = p.L75= on NM_014041.5) | Silent (SNP) | VAF 52/632 reads (8%) | called by muse, mutect2
- SPTBN1 | c.4533G>T p.T1511= | Silent (SNP) | VAF 189/996 reads (19%) | called by muse, mutect2, varscan2
- TOP2B | c.864T>C p.F288= (on ENST00000264331 / NM_001330700.2; = p.F283= on NM_001068.3) | Silent (SNP) | VAF 58/391 reads (15%) | called by muse, mutect2, varscan2
- TRPC7 | c.477G>A p.T159= | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as rs1373580789; called by muse, mutect2, varscan2
- UNC79 | c.3666G>A p.K1222= (on ENST00000393151 / NM_001346218.2; = p.K1045= on NM_020818.5) | Silent (SNP) | VAF 119/571 reads (21%) | called by muse, mutect2, varscan2
- VCAM1 | c.1254G>T p.G418= | Silent (SNP) | VAF 15/334 reads (4%) | called by muse, mutect2
- VWA5B1 | c.3090G>A p.L1030= (on ENST00000375079; = p.L1025= on NM_001039500.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/384 reads (9%) | called by muse, mutect2
- ABCA4 | c.-23C>G | 5'UTR (SNP) | VAF 80/1022 reads (8%) | catalogued as rs749827888, COSV100933252; called by muse, mutect2
- AC011410.1 | n.424C>A | RNA (SNP) | VAF 35/338 reads (10%) | called by muse, mutect2
- ANXA8L1 | c.207+123G>T | Intron (SNP) | VAF 90/528 reads (17%) | called by muse, varscan2
- ARHGEF4 | c.-420C>A | 5'UTR (SNP) | VAF 44/193 reads (23%) | called by muse, mutect2, varscan2
- CELA3A | chr1:21998188 A>T | 5'Flank (SNP) | VAF 16/472 reads (3%) | called by muse, mutect2
- HSPG2 | c.10454-68C>T | Intron (SNP) | VAF 41/407 reads (10%) | called by muse, mutect2
- IGFN1 | c.1242-1994G>T | Intron (SNP) | VAF 115/750 reads (15%) | called by muse, mutect2, varscan2
- MYADML | n.1082T>A | RNA (SNP) | VAF 48/490 reads (10%) | called by muse, mutect2
- MYPN | c.*632A>T | 3'UTR (SNP) | VAF 426/2161 reads (20%) | called by muse, mutect2, varscan2
- NMI | c.81+18G>T | Intron (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1261C>A | RNA (SNP) | VAF 114/580 reads (20%) | called by muse, mutect2, varscan2
- OFCC1 | n.1040C>T | RNA (SNP) | VAF 82/539 reads (15%) | called by muse, mutect2, varscan2
- OR2L1P | n.662G>T | RNA (SNP) | VAF 113/598 reads (19%) | catalogued as rs991513076; called by muse, mutect2, varscan2
- PIPSL | n.1319T>C | RNA (SNP) | VAF 119/358 reads (33%) | catalogued as rs749739706; called by muse, mutect2, varscan2
- PLCE1 | c.*21C>A | 3'UTR (SNP) | VAF 117/523 reads (22%) | catalogued as COSV99592971; called by muse, mutect2, varscan2
- PNPO | c.417+313G>T | Intron (SNP) | VAF 62/670 reads (9%) | catalogued as COSV56666943; called by muse, mutect2
- SLC13A5 | c.369-312G>A | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- SLC19A3 | c.1172+36A>T | Intron (SNP) | VAF 78/429 reads (18%) | called by muse, mutect2, varscan2
- SLIT1 | c.1086-812C>A | Intron (SNP) | VAF 72/223 reads (32%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-2436G>C | Intron (SNP) | VAF 197/679 reads (29%) | called by muse, mutect2, varscan2
- STK19 | c.567+16G>C | Intron (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2, varscan2
- SULT1A1 | c.-53C>T | 5'UTR (SNP) | VAF 12/150 reads (8%) | catalogued as rs1392720498; called by muse, mutect2
- TBX3 | c.718-37T>C | Intron (SNP) | VAF 46/284 reads (16%) | called by muse, mutect2, varscan2
- TRBV29-1 | c.-12C>A | 5'UTR (SNP) | VAF 108/966 reads (11%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25072592 del C | 3'Flank (DEL) | VAF 129/1064 reads (12%) | called by mutect2, pindel, varscan2
- Y_RNA | chr7:74896480 G>T | 3'Flank (SNP) | VAF 121/1175 reads (10%) | called by muse, mutect2, varscan2
